Somatic mutation profile of cancer-model specimen HCM-SANG-0271-D12-85B (3D Organoid; aliquot HCM-SANG-0271-D12-85B-01D-A80U-36), derived from the primary tumor of HCMI case HCM-SANG-0271-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Tubular adenoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0271-D12-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86fb843e-a3a7-4ae9-b384-10f076875a71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0271-D12-10A (Blood Derived Normal), aliquot HCM-SANG-0271-D12-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ee85ad2-9c65-4e58-89ef-278bc7e7d478

The open-access MAF lists 178 somatic variants for this specimen: 127 protein-altering or splice-affecting, 44 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 44, Nonsense Mutation 12, Intron 4, Frame Shift Del 3, In Frame Del 2, Splice Region 2, Splice Site 2, 5'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3186_3187del p.S1063* | Frame Shift Del (DEL) | VAF 109/232 reads (47%) | catalogued as rs1060503362; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 186/367 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 181/368 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782620, CM132087, COSV52665025, COSV53025766, COSV53135444, COSV53176166; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- ADAMTS13 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 278/533 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs782511560; called by muse, mutect2, varscan2
- ADCY9 | c.3518C>T p.T1173M | Missense Mutation (SNP) | VAF 232/589 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1371707087, COSV53572532; called by muse, mutect2
- AKIRIN1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs1315318370; called by muse, mutect2, varscan2
- ALK | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 144/523 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs745499366, COSV66577674; ClinVar: uncertain significance; called by muse, varscan2
- ATP13A5 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1393318983; called by muse, mutect2, varscan2
- B3GALT5 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 146/310 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1454210645; called by muse, mutect2, varscan2
- BIRC6 | c.13730G>A p.R4577H | Missense Mutation (SNP) | VAF 319/488 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101428256; called by muse, mutect2, varscan2
- CCN5 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 138/2448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778811911; called by muse, mutect2
- COL12A1 | c.4795C>T p.R1599* | Nonsense Mutation (SNP) | VAF 46/328 reads (14%) | catalogued as COSV100485159, COSV59401096; called by muse, mutect2, varscan2
- CSMD3 | c.7032C>G p.D2344E (on ENST00000297405 / NM_001363185.1; = p.D2240E on NM_052900.3) | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV52334770; called by muse, mutect2, varscan2
- CXCR4 | c.82T>A p.C28S | Missense Mutation (SNP) | VAF 148/462 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54009986; called by muse, mutect2, varscan2
- DACT1 | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 104/510 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.29); catalogued as rs764224780; called by muse, mutect2, varscan2
- DCDC1 | c.3394C>A p.L1132I (on ENST00000597505 / NM_001367979.1; = p.L239I on NM_020869.3) | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.178); catalogued as COSV60305246, COSV60308419; called by muse, mutect2, varscan2
- DOK7 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 449/449 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs769289951; called by muse, mutect2, varscan2
- EPHA3 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs773476878, COSV60719749; called by muse, mutect2, varscan2
- ERICH4 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 289/410 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs782111142; called by muse, mutect2, varscan2
- ERVMER34-1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 173/421 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs1051087038; called by muse, mutect2, varscan2
- FAM110A | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 353/1047 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs957098379; called by muse, mutect2, varscan2
- FOSB | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 51/356 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1180159338; called by muse, mutect2, varscan2
- FRG2B | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as rs754809295; called by mutect2, varscan2
- H2BC11 | c.94C>G p.R32G | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs769130601; called by muse, mutect2, varscan2
- HECTD1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1200713364, COSV67947686; called by muse, mutect2, varscan2
- HK3 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 224/333 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771626485, COSV52842984; called by muse, mutect2, varscan2
- HRNR | c.1699A>T p.R567W | Missense Mutation (SNP) | VAF 222/490 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as rs1191808120, COSV64255120; called by muse, varscan2
- IGSF10 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 173/340 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs374510873, COSV99193968; called by muse, varscan2
- KCNB2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 87/410 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV73050947, COSV73053233; called by muse, mutect2, varscan2
- KCNMA1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54237087, COSV54243900; called by muse, mutect2, varscan2
- KIF19 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 145/416 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs765728283, COSV63428708; called by muse, mutect2, varscan2
- KRR1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 152/434 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs549769836, COSV56991708; called by muse, mutect2, varscan2
- KRT23 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 291/587 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs750245687, COSV52926972, COSV52929212; called by muse, mutect2, varscan2
- LZTR1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 172/382 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs970027059, COSV99301246; called by muse, mutect2, varscan2
- MAGEA12 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 102/423 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs1556833500, COSV100757013, COSV63295146; called by muse, varscan2
- MAGEB10 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 236/438 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs754281513; called by muse, mutect2, varscan2
- MAGEB6B | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 61/329 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1046848646; called by muse, mutect2, varscan2
- MBNL2 | c.727A>C p.K243Q | Missense Mutation (SNP) | VAF 390/817 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.501); catalogued as COSV59117309; called by muse, mutect2, varscan2
- MINAR1 | c.2299-1G>C p.X767_splice | Splice Site (SNP) | VAF 46/274 reads (17%) | catalogued as COSV59586069; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 87/700 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.745); catalogued as rs760012733; called by muse, mutect2, varscan2
- MYH14 | c.2975C>T p.T992M | Missense Mutation (SNP) | VAF 321/481 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs201746408, COSV51826998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.4402G>C p.E1468Q | Missense Mutation (SNP) | VAF 171/473 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs755024942; called by muse, mutect2, varscan2
- NBR1 | c.244G>C p.V82L | Missense Mutation (SNP) | VAF 150/304 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV57835849; called by muse, mutect2, varscan2
- NUDT4 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV100455689; called by muse, varscan2
- OCSTAMP | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 362/1864 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs868469717, COSV99645009; called by muse, mutect2, varscan2
- PLXNA2 | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 97/572 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs771610537, COSV65439741; called by muse, mutect2, varscan2
- PLXNA4 | c.4029C>A p.Y1343* | Nonsense Mutation (SNP) | VAF 50/376 reads (13%) | catalogued as COSV100325046; called by mutect2, varscan2
- PTPRS | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 293/575 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs1224185745; called by muse, mutect2, varscan2
- RRAGC | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs761415462, COSV65931302; called by muse, mutect2, varscan2
- RYR2 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs1283158734; called by muse, mutect2, varscan2
- SIX6 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 202/462 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs886050563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO3A1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 303/574 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV59229085; called by muse, mutect2, varscan2
- SSH3 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 168/440 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200078645; called by muse, mutect2, varscan2
- SUFU | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 211/374 reads (56%) | catalogued as COSV64014466; called by muse, mutect2, varscan2
- TCF4 | c.525A>C p.K175N | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV61891740; called by muse, mutect2, varscan2
- TDRD9 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs781139035; called by muse, mutect2, varscan2
- TNFRSF11A | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 78/363 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1020903615, COSV54022728; called by muse, mutect2, varscan2
- TPO | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 345/1000 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs1173922703; called by muse, mutect2
- URGCP | c.682C>A p.L228M (on ENST00000453200 / NM_001077663.3; = p.L219M on NM_017920.4) | Missense Mutation (SNP) | VAF 119/746 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.64); catalogued as COSV56250117; called by muse, mutect2, varscan2
- ZC3H12C | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 145/388 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1256899304; called by muse, mutect2, varscan2
- ZFPM2 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 316/530 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770304470; called by muse, mutect2, varscan2
- ZNF614 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 114/341 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs778179613; called by muse, mutect2, varscan2
- AASS | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 186/642 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- AATK | c.2415G>C p.E805D (on ENST00000326724 / NM_001080395.3; = p.E702D on NM_004920.2) | Missense Mutation (SNP) | VAF 319/539 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACVR1C | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 70/503 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTSL3 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 97/315 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADARB2 | c.1683-8C>A | Splice Region (SNP) | VAF 457/458 reads (100%) | called by muse, mutect2, varscan2
- AL592490.1 | c.1578A>C p.L526F | Missense Mutation (SNP) | VAF 57/506 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- APOB | c.1622A>T p.Q541L | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ARHGAP24 | c.440A>C p.Y147S (on ENST00000395184 / NM_001025616.3; = p.Y54S on NM_031305.3) | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ASCC3 | c.817G>T p.G273* | Nonsense Mutation (SNP) | VAF 28/273 reads (10%) | called by muse, mutect2, varscan2
- BRWD3 | c.2961G>T p.K987N | Missense Mutation (SNP) | VAF 142/296 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC168 | c.8731C>T p.Q2911* | Nonsense Mutation (SNP) | VAF 149/622 reads (24%) | called by muse, mutect2, varscan2
- CHD4 | c.5083_5086+1dup p.X1695_splice (on ENST00000357008 / NM_001363606.2; = p.X1706_splice on NM_001273.5) | Splice Site (INS) | VAF 160/263 reads (61%) | called by mutect2, pindel, varscan2
- CLEC5A | c.46A>C p.K16Q | Missense Mutation (SNP) | VAF 128/511 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CNNM1 | c.544A>C p.K182Q | Missense Mutation (SNP) | VAF 164/501 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- COX7A2 | c.176A>T p.K59I | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DGKI | c.1689C>A p.F563L | Missense Mutation (SNP) | VAF 45/434 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- DOK5 | c.236C>G p.A79G | Missense Mutation (SNP) | VAF 156/1259 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- FER1L5 | c.2146C>G p.L716V (on ENST00000623019; = p.L721V on NM_001293083.2) | Missense Mutation (SNP) | VAF 24/892 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GBP7 | c.1528A>T p.K510* | Nonsense Mutation (SNP) | VAF 139/343 reads (41%) | called by muse, mutect2, varscan2
- GPI | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 235/649 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2AC12 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- HSP90AA1 | c.449_450del p.V150Dfs*5 | Frame Shift Del (DEL) | VAF 112/335 reads (33%) | called by pindel, varscan2
- IRS2 | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 96/952 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KANK2 | c.1194C>A p.N398K | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCND1 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 284/595 reads (48%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCTD9 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- LARGE1 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 63/333 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC9 | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 60/345 reads (17%) | called by muse, mutect2, varscan2
- LYZL1 | c.285C>A p.C95* (on ENST00000375500; = p.C49* on NM_032517.6) | Nonsense Mutation (SNP) | VAF 152/370 reads (41%) | called by muse, mutect2, varscan2
- MACF1 | c.19040G>T p.R6347I (on ENST00000372915; = p.R4392I on NM_012090.5) | Missense Mutation (SNP) | VAF 82/303 reads (27%) | called by muse, mutect2, varscan2
- MBD5 | c.4190C>A p.T1397N | Missense Mutation (SNP) | VAF 87/530 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MRPL38 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 119/553 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MRRF | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 89/152 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MYCBP2 | c.12362G>C p.S4121T (on ENST00000357337; = p.S4159T on NM_015057.5) | Missense Mutation (SNP) | VAF 53/619 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.444); called by muse, mutect2
- OR10A6 | c.834C>G p.Y278* | Nonsense Mutation (SNP) | VAF 28/509 reads (6%) | called by muse, mutect2
- OR5L2 | c.615G>C p.L205F | Missense Mutation (SNP) | VAF 130/364 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OXSM | c.1271A>T p.Y424F | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PCDHA1 | c.2236G>T p.G746W | Missense Mutation (SNP) | VAF 108/323 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCMTD1 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 131/311 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PIKFYVE | c.1648T>A p.S550T | Missense Mutation (SNP) | VAF 124/351 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PKM | c.806G>T p.S269I | Missense Mutation (SNP) | VAF 163/328 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PRAME | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 169/397 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- PRR29 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 84/504 reads (17%) | called by muse, mutect2, varscan2
- RASGRP3 | c.1362_1364del p.F454del (on ENST00000402538 / NM_001349975.2; = p.F453del on NM_015376.2 and 4 other RefSeq transcripts) | In Frame Del (DEL) | VAF 78/365 reads (21%) | called by pindel, varscan2
- RASSF10 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 294/607 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM46 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF6 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 84/660 reads (13%) | called by muse, mutect2, varscan2
- SASH1 | c.2208C>A p.N736K | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SLAIN1 | c.1405T>C p.S469P (on ENST00000466548; = p.S206P on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/669 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYCP2 | c.2181del p.L728Sfs*2 | Frame Shift Del (DEL) | VAF 72/820 reads (9%) | called by mutect2, pindel
- SYNGR2 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 137/800 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TAPBP | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 171/484 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TBC1D5 | c.1142T>A p.I381N | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TEX55 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- TP53I11 | c.180G>C p.L60F | Missense Mutation (SNP) | VAF 132/337 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); called by muse, mutect2
- TRIM64 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TRPV1 | c.1044G>A p.G348= | Splice Region (SNP) | VAF 114/241 reads (47%) | called by muse, mutect2, varscan2
- VEGFD | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 74/378 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- WDR75 | c.1984_1986del p.S662del | In Frame Del (DEL) | VAF 155/246 reads (63%) | called by mutect2, pindel, varscan2
- XPO1 | c.2554C>T p.L852F | Missense Mutation (SNP) | VAF 52/342 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZBTB1 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 312/313 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZC3H11A | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF284 | c.1443A>C p.K481N | Missense Mutation (SNP) | VAF 119/349 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF607 | c.1893_1900del p.Y631* | Nonsense Mutation (DEL) | VAF 60/532 reads (11%) | called by mutect2, pindel
- ZNF844 | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 140/300 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, varscan2
- ADAMTS2 | c.2109C>T p.I703= | Silent (SNP) | VAF 116/196 reads (59%) | catalogued as rs200210415, COSV52375142; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- ADD2 | c.45G>A p.P15= | Silent (SNP) | VAF 193/677 reads (29%) | catalogued as COSV52469298; called by muse, mutect2, varscan2
- AK9 | c.2478C>T p.P826= | Silent (SNP) | VAF 212/278 reads (76%) | catalogued as rs958543521, COSV58139097, COSV58140680; called by muse, varscan2
- CCDC186 | c.1680G>A p.L560= | Silent (SNP) | VAF 91/136 reads (67%) | called by muse, mutect2, varscan2
- CHST10 | c.270C>T p.N90= | Silent (SNP) | VAF 163/526 reads (31%) | catalogued as rs148626049, COSV99958968; called by muse, mutect2, varscan2
- CNTN6 | c.921T>A p.L307= | Silent (SNP) | VAF 54/236 reads (23%) | called by muse, mutect2, varscan2
- CSMD1 | c.4767C>T p.Y1589= (on ENST00000520002; = p.Y1588= on NM_033225.6) | Silent (SNP) | VAF 191/384 reads (50%) | catalogued as rs1258606725; called by muse, mutect2, varscan2
- DLX5 | c.696G>T p.S232= | Silent (SNP) | VAF 255/844 reads (30%) | called by muse, mutect2, varscan2
- ELP2 | c.174C>T p.T58= | Silent (SNP) | VAF 63/289 reads (22%) | catalogued as rs150889303, COSV52369120; called by muse, mutect2, varscan2
- FCRL4 | c.750C>T p.T250= | Silent (SNP) | VAF 361/361 reads (100%) | catalogued as rs775384031, COSV99619138; called by muse, mutect2, varscan2
- FIGN | c.1074C>T p.N358= | Silent (SNP) | VAF 220/700 reads (31%) | called by muse, mutect2, varscan2
- GDF6 | c.1014C>T p.F338= | Silent (SNP) | VAF 79/328 reads (24%) | catalogued as rs1474559057, COSV99747493; called by muse, mutect2, varscan2
- GGH | c.783A>T p.A261= | Silent (SNP) | VAF 82/433 reads (19%) | called by muse, mutect2, varscan2
- GOLM2 | c.96C>T p.Y32= | Silent (SNP) | VAF 257/488 reads (53%) | called by muse, mutect2, varscan2
- GPR132 | c.201G>A p.A67= | Silent (SNP) | VAF 443/443 reads (100%) | catalogued as rs575453416, COSV61677884; called by muse, varscan2
- GPR32 | c.234C>A p.T78= | Silent (SNP) | VAF 206/676 reads (30%) | catalogued as rs771826086; called by muse, mutect2, varscan2
- HECTD4 | c.4401G>A p.T1467= | Silent (SNP) | VAF 273/437 reads (62%) | catalogued as rs533197509, COSV61180963; called by muse, mutect2, varscan2
- IFIT1 | c.552T>C p.S184= | Silent (SNP) | VAF 227/228 reads (100%) | called by muse, mutect2, varscan2
- KBTBD13 | c.969C>T p.Y323= | Silent (SNP) | VAF 245/490 reads (50%) | catalogued as rs568613948, COSV71351377; called by muse, mutect2, varscan2
- KCNMB1 | c.159C>T p.C53= | Silent (SNP) | VAF 60/241 reads (25%) | called by muse, mutect2, varscan2
- KRT7 | c.150C>T p.A50= | Silent (SNP) | VAF 24/721 reads (3%) | called by muse, mutect2
- MAST1 | c.1182C>T p.R394= | Silent (SNP) | VAF 138/267 reads (52%) | catalogued as rs778656447, COSV52248363; called by muse, mutect2, varscan2
- MYH13 | c.1902C>G p.S634= | Silent (SNP) | VAF 92/193 reads (48%) | called by muse, mutect2, varscan2
- NACAD | c.3816G>A p.P1272= | Silent (SNP) | VAF 204/798 reads (26%) | catalogued as rs888779393, COSV101512091; called by muse, mutect2, varscan2
- NAT10 | c.2109C>T p.A703= | Silent (SNP) | VAF 174/381 reads (46%) | catalogued as rs779738249; called by muse, mutect2, varscan2
- NRIP1 | c.1029T>C p.A343= | Silent (SNP) | VAF 88/262 reads (34%) | called by muse, mutect2, varscan2
- NXF3 | c.861G>A p.T287= | Silent (SNP) | VAF 170/384 reads (44%) | catalogued as rs201477119, COSV67702814; called by muse, mutect2, varscan2
- OR2H1 | c.261G>A p.K87= | Silent (SNP) | VAF 239/679 reads (35%) | called by muse, mutect2, varscan2
- PDP1 | c.546C>T p.S182= | Silent (SNP) | VAF 193/560 reads (34%) | catalogued as rs202034256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITX1 | c.486G>A p.P162= | Silent (SNP) | VAF 97/322 reads (30%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4030C>A p.R1344= | Silent (SNP) | VAF 54/412 reads (13%) | catalogued as rs375720148; called by muse, mutect2, varscan2
- POLR2H | c.102T>A p.S34= | Silent (SNP) | VAF 135/312 reads (43%) | called by muse, mutect2, varscan2
- PTPRT | c.1290C>T p.F430= | Silent (SNP) | VAF 208/1382 reads (15%) | called by muse, mutect2, varscan2
- RNF133 | c.351A>G p.K117= | Silent (SNP) | VAF 246/593 reads (41%) | called by muse, mutect2, varscan2
- RNF213 | c.14901C>A p.G4967= | Silent (SNP) | VAF 60/431 reads (14%) | catalogued as rs775932728; called by muse, mutect2, varscan2
- SDHA | c.117G>C p.G39= | Silent (SNP) | VAF 70/369 reads (19%) | catalogued as CD137030, COSV99371562; called by muse, mutect2, varscan2
- SKOR2 | c.699C>T p.A233= | Silent (SNP) | VAF 94/386 reads (24%) | called by muse, varscan2
- SLC12A5 | c.270C>T p.N90= (on ENST00000454036 / NM_001134771.2; = p.N67= on NM_020708.5) | Silent (SNP) | VAF 78/1474 reads (5%) | called by muse, mutect2
- TEX37 | c.111G>A p.T37= | Silent (SNP) | VAF 58/373 reads (16%) | catalogued as rs370424706; called by muse, mutect2, varscan2
- TRIM23 | c.1659A>T p.G553= | Silent (SNP) | VAF 96/281 reads (34%) | called by muse, mutect2, varscan2
- UBASH3B | c.447C>T p.T149= | Silent (SNP) | VAF 143/440 reads (33%) | catalogued as rs1211610353; called by muse, mutect2, varscan2
- ZIC1 | c.1026C>G p.R342= | Silent (SNP) | VAF 119/270 reads (44%) | called by muse, mutect2, varscan2
- ZNF175 | c.1827C>T p.H609= | Silent (SNP) | VAF 71/467 reads (15%) | catalogued as rs1455422704; called by muse, mutect2, varscan2
- ZNF71 | c.414C>G p.A138= | Silent (SNP) | VAF 126/636 reads (20%) | called by muse, mutect2, varscan2
- ADAP1 | chr7:955399 C>G | 5'Flank (SNP) | VAF 44/377 reads (12%) | called by muse, mutect2, varscan2
- DAPK2 | c.858+1789T>C | Intron (SNP) | VAF 149/284 reads (52%) | called by muse, mutect2, varscan2
- DNAH9 | c.904+32T>C | Intron (SNP) | VAF 207/427 reads (48%) | catalogued as rs774772560; called by muse, mutect2, varscan2
- KIR3DX1 | n.29G>C | RNA (SNP) | VAF 150/520 reads (29%) | catalogued as rs535648212, COSV55601555; called by muse, mutect2, varscan2
- KPNA4 | c.-227C>T | 5'UTR (SNP) | VAF 61/312 reads (20%) | catalogued as rs1052285159; called by muse, mutect2, varscan2
- NUDT7 | c.190-326G>A | Intron (SNP) | VAF 88/195 reads (45%) | catalogued as rs965893001; called by muse, mutect2, varscan2
- ZNF665 | c.-54+10428G>C | Intron (SNP) | VAF 59/335 reads (18%) | called by muse, mutect2, varscan2
